Surgical pathology report (de-identified scan), TCGA case TCGA-55-8510, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8510-01A (Primary Tumor).

[page 1 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - G.) LUNG, RIGHT, LOWER LOBE, PERIBRONCHIAL (N11R X2), HILAR (N10R), SUBCARINAL (N7R), AND LOWER PARATRACHEAL (N4R) LYMPH NODES, WEDGE EXCISION WITH SUBSEQUENT LOBECTOMY AND REGIONAL LYMPH NODE DISSECTION:

- POORLY DIFFERENTIATED ADENOCARCINOMA, COMPATIBLE WITH LUNG ORIGIN.
- 1.5 cm in maximum dimension.
- Visceral pleura invasion: PRESENT.
- MARGIN STATUS: NEGATIVE.
- NINE LYMPH NODES, NEGATIVE FOR METASTASIS (0/9).
- INCIDENTAL SPINDLE CELL CARCINOID.
- 0.5 cm in greatest dimension.
- SEE TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Adenocarcinoma, poorly differentiated.

Primary tumor: pT2a (1.5 cm in greatest dimension, invading the visceral pleura).

Regional lymph nodes: pN0 (9 lymph nodes, negative for metastasis).

Distant metastasis: Not applicable.

Pathologic stage: IB.

Lymphovascular invasion: Not identified.

Margin status: R0.

Lung Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol, [REDACTED]

[page 2 of 5]
Procedure:	Lobectomy.
Specimen type:	Lung, lower lobe.
Specimen laterality:	Right.
Specimen integrity:	Intact.
TUMOR FEATURES:	
Tumor site:	Lung, lower lobe.
Tumor size:	Greatest dimension: 1.5 cm. Additional dimensions: 1.5 x 1 cm
Tumor focality:	Unifocal.
Histologic type:	Adenocarcinoma.
Histologic grade:	Poorly differentiated (G3).
Lymphovascular invasion:	Not identified.
Perineural invasion:	Not identified.
Visceral pleura invasion:	Present.
Tumor extension into extrapulmonary structures:	Not identified.
Treatment effect:	Not applicable.
LYMPH NODES:	Nine lymph nodes, negative for metastasis.
MARGIN EVALUATION:	Negative.
Distance to closest margin:	Unable to determine; tumor present in wedge excision, however, no residual tumor present in subsequent lobectomy.
Bronchial margin:	Uninvolved by carcinoma.
Vascular margin:	Uninvolved by carcinoma.
Parenchymal margin:	Uninvolved by carcinoma.
Parietal pleural margin:	Not applicable.
Chest wall margin:	Not applicable.
Other margins:	Not applicable.
PATHOLOGIC TUMOR STAGING DESCRIPTORS:	
Primary tumor:	pT2a (1.5 cm in greatest dimension, with invasion into visceral pleura).
Regional lymph nodes:	pN0 (nine lymph nodes, negative for metastasis).
Distant metastasis:	Not applicable.
Margin status:	R0.
Pathologic stage:	IB.
Additional pathologic findings:	Incidental spindle cell carcinoid tumor (0.5 cm in greatest dimension). Emphysematous changes.
Comment:	N/A

[page 3 of 5]
Source of Specimen:

- A. Right lower lobe lung wedge excision
- B. Lung; Right lower lobe for bronchial margins
- C. Lymph node; N11R
- D. Lymph node; N11R #2
- E. Lymph node; N7R
- F. Lymph node; N4R
- G. Lymph node; N10R

Clinical History/Operative Dx:

Right lung nodule

Intraoperative Diagnosis:

- A. FSA: Right lower lobe lung wedge excision: Non-small cell carcinoma, favor adenocarcinoma. (Dr. [REDACTED])

- B. FSB: Right lower lobe of lung lobectomy: Bronchial margin free of tumor. (Dr. [REDACTED])

Gross Description:

A. The specimen is labeled Right lower lobe wedge excision and is received without fixative. It consists of a wedge excision of tan to purplish lung tissue measuring 7.5 x 3.4 x 1.8 cm. It has a fixed weight of 17 grams. A metallic staple line is present along one edge. The pleural surface shows some anthracotic stippling. Centrally there has been a previous incision made to reveal a subpleural gray-tan tumor mass which measures 1.5 x 1.5 x 1 cm. A representative sections of the tumor mass is submitted for frozen section as FSA. Representative tumor is obtained for research purposes. The tumor is immediately subpleural and is 0.4 cm from the closest staple line. The tissue remaining from frozen section is submitted for permanent section in cassette A1. Sections of the tumor and closest approach to pleural surface are submitted in cassette A2, A3-A4 is sections of tumor with closest approach to staple line (inked green), A5) sections of uninvolved lung. [REDACTED]

B. The specimen is labeled right lower lobe and is received without fixative. It consists of a lobe of lung which measures 8.5 x 7.5 x 5 cm and weighs 163 grams in the fixed state. The pleural surface is pale violet to reddish violet and smooth. Along the apical portion are multiple metallic staple lines. The pleural surfaces are predominantly smooth with the exception of a small 0.4 cm plaque-like area of whitish discoloration located 2.5 cm from the superior staple line along the anterolateral surface. At the hilum the

[page 4 of 5]
FINAL SURGICAL PATHOLOGY REPORT

bronchial margin is identified and removed as a thin shave, submitted for frozen section. There are no appreciable peribronchial nodes. Dissection of the bronchi reveals no intrabronchial tumor. The lung is serially sectioned at close intervals to reveal consolidated dark red pulmonary parenchyma without discrete masses. Representative sections are submitted. Section summary: B1) bronchial margin from frozen section, B2) vascular margins, B3) possible small peribronchial nodes, B4) plaque-like pleural discoloration (pleural surface inked), B5) apical lung sections along staple lines and three small peribronchial nodes, B6) apical and mid lung, B7) basilar lung. [REDACTED]

C. The specimen is N11R and is received in formalin. It consists of a 0.7 x 0.5 x 0.5 cm fragment of gray-tan anthracotic tissue. It is serially sectioned and submitted in cassette C1. [REDACTED]

D. The specimen is labeled N11R#2 and is received in formalin. It consists of three 0.2 - 0.7 cm fragments of gray-tan to red-brown tissue which are submitted in cassette D1. [REDACTED]

E. The specimen is labeled N7R and is received in formalin. It consists of two fragments of fibrofatty tissue which vary from 0.6 x 0.5 x 0.3 cm to 1.1 x 0.7 x 0.7 cm. The smaller fragment contains a discrete 0.4 cm gray-tan nodule. The larger fragment contains gray-tan moderately firm tissue. The larger fragment is inked. It is serially sectioned and combined with the remaining tissue in cassette E1. [REDACTED]

F. The specimen is labeled N4R and is received in formalin. It consists of multiple fragments of fibrofatty tissue measuring 1.5 x 1.2 x 0.2 cm in aggregate. The tissue is entirely submitted in cassette F1. [REDACTED]

G. The specimen is labeled N10R and is received in formalin. It consists of a 0.2 cm fragment of dark brown to black tissue which is submitted in cassette G1. [REDACTED]

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Elastic stain, performed on block A2 with adequate control, confirms the presence of visceral pleural invasion. Immunohistochemical studies performed on the primary tumor (block A2) reveal the neoplastic cells to be positive for CK7, MOC-31, Napsin-A, and TTF-1, and negative for CK5/6 and p63, compatible with pulmonary adenocarcinoma. The incidental small lesion (block A4) is positive for CK7, chromogranin, synaptophysin, and CD56, and negative for EMA, p63, and PR, supporting the interpretation of carcinoid tumor. The Ki-67 proliferative index is low (<10%), making small cell carcinoma unlikely.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Three peribronchial lymph nodes are identified, and are negative for metastasis.

C. Sections demonstrate one lymph node, negative for metastasis.

D. Sections demonstrate one lymph node, negative for metastasis.

E. Sections demonstrate two lymph nodes, negative for metastasis.

F. Sections demonstrate one lymph node, negative for metastasis.

[page 5 of 5]
FINAL SURGICAL PATHOLOGY REPORT

G. Sections demonstrate one lymph node, negative for metastasis.

Source: NCI Genomic Data Commons file 0e2e1534-5921-49e6-93cb-ff30af80c7f5 (TCGA-55-8510.54AD9F1A-326F-4CC6-991A-6717BFBAED35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).